CGCI case HTMCP-02-03-01018 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ed61e467-7c73-42d4-8359-4a8e6673e977

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,013 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T1a; AJCC clinical N: N0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,096 days (5.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Surgery, NOS.

Follow-up (5 entries)
- Days to follow up: 0 days; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 863 days (2.4 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 863 days (2.4 years).
- Days to follow up: 1,992 days (5.5 years); Disease response: With Tumor.
- Days to follow up: 2,096 days (5.7 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -7,670.

Other clinical attributes
- Day -7,670: Risk factors: HIV/AIDS.
- Day -7,670: Comorbidities: HIV/AIDS.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Weight: 100.7 kg; CD4 count: 348; Haart treatment indicator: Yes; HIV viral load: 50.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.
- Day 0: Risk factors: Hepatitis C Infection.
- Day 1,992: Nadir CD4 count: 256.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 15; Tobacco smoking quit year: 1997.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01018-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01018-11B: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; Tumor status: With tumor; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Performance status timing: Preoperative; Tobacco smoking history indicator: 4.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1990; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: Yes; Cdc HIV risk group: IV drug user; History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Method initial path diagnosis: Tumor resection; Days from index date to tumor sample procurement: 2.
- Follow-up form: Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
